Gene-level copy-number profile of tumor specimen TCGA-TQ-A7RM-01A from TCGA case TCGA-TQ-A7RM, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 41.5 years (15,154 days).
Specimen TCGA-TQ-A7RM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.13d2014f-340a-4b2c-be23-e6754b1e0b40.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-TQ-A7RM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bb22d568-cc02-4979-b40b-50cba6e2debd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 414; copy number 2: 3,937; copy number 3: 8,674; copy number 4: 38,812; copy number 5: 2,898; copy number 6: 3,569; copy number 7: 1,115; copy number 8: 368; copy number 9: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-TQ-A7RM-01A-11D-A33S-01): tumor purity 0.92, ploidy 3.97, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,232,612–48,599,436, 8 genes (within-gene range 0–2): ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:95,834,424–96,779,595, 16 genes, copy number 9 (within-gene range 6–9): GGCTP1, AC008592.3, LINC01554, AC008592.4, AC008592.1, ELL2, AC104123.1, AC008592.2, FABP5P5, MIR583HG, MIR583, RNU6-524P, AC099509.1, AC099509.2, PCSK1, CAST.

Autosomal genes at a single copy (total copy number 1): 414. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
